Somatic mutation profile of tumor specimen MMRF_2138_1_BM_CD138pos (aliquot MMRF_2138_1_BM_CD138pos_T1_KHS5U_L08662) from MMRF case MMRF_2138, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.5 years (29,779 days).
Specimen MMRF_2138_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdfaca71-9a6a-4203-ab31-8682e840bfcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2138_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2138_1_PB_Whole_C2_KHS5U_L08663; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdca3201-65f8-4fde-a856-2fd7ebaf7519

The open-access MAF lists 123 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 27, Intron 16, Silent 15, 5'Flank 6, Nonsense Mutation 5, 5'UTR 3, RNA 3, Frame Shift Del 2, In Frame Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACBD5 | c.353T>C p.V118A (on ENST00000375888 / NM_001352568.1; = p.V120A on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs751857303; called by muse, mutect2, varscan2
- ALG10B | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.076); catalogued as rs759390656; called by muse, mutect2, varscan2
- BMP7 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67780993; called by muse, mutect2, varscan2
- CAPN13 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.055); catalogued as rs1324487447, COSV54428836; called by muse, mutect2
- DNAH10 | c.3829G>T p.G1277* (on ENST00000409039; = p.G1216* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV101292048; called by muse, mutect2, varscan2
- DNAH12 | c.6308G>A p.R2103Q (on ENST00000351747; = p.R2122Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs926019904; called by muse, mutect2
- FASN | c.7094C>T p.T2365M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs775705403; called by muse, mutect2, varscan2
- GRM7 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs952338137, COSV63143156; called by muse, mutect2, varscan2
- HPCA | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs964186002, COSV65103405; called by muse, mutect2, varscan2
- IGHV2-70 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs569335455; called by muse, varscan2
- MKLN1 | c.1277G>A p.S426N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV61761570; called by muse, mutect2, varscan2
- MMP20 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99497375; called by muse, mutect2
- OR2T1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV63543034; called by muse, mutect2, varscan2
- PLEKHA6 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs377234378; called by muse, mutect2, varscan2
- RNF151 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.473); catalogued as COSV58399106; called by muse, mutect2, varscan2
- RNF34 | c.964_966del p.D322del | In Frame Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs1555283773; called by pindel, varscan2
- RNF6 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs1271456198; called by muse, mutect2, varscan2
- ZNF646 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs777007769, COSV100336267; called by muse, mutect2, varscan2
- AKAP6 | c.5376G>T p.M1792I | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAAT | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 49/238 reads (21%) | called by muse, mutect2, varscan2
- BBS12 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD300LG | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2
- COMP | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- DNAH5 | c.3230C>A p.S1077Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EFHB | c.2359A>T p.K787* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- EGLN1 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- FIP1L1 | c.1701del p.K567Nfs*55 | Frame Shift Del (DEL) | VAF 68/388 reads (18%) | called by mutect2, pindel, varscan2
- FLT4 | c.2999_3001del p.E1000del | In Frame Del (DEL) | VAF 62/190 reads (33%) | called by pindel, varscan2
- FOXP2 | c.1336A>C p.T446P | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, varscan2
- GCDH | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); called by muse, mutect2
- IER2 | c.464A>C p.E155A | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, varscan2
- IGF1R | c.2408T>G p.I803S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KIAA2026 | c.1142A>T p.Y381F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- LY6L | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.072); called by muse, mutect2
- NT5E | c.1103T>A p.M368K | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- NUMBL | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- PAN2 | c.1532A>C p.Y511S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCK2 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PDZD2 | c.7259T>C p.I2420T | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLSCR5 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRSS1 | c.176T>A p.V59E | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, varscan2
- RAPH1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RASA2 | c.1834T>C p.Y612H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN8A | c.4697_4701del p.T1566Rfs*40 | Frame Shift Del (DEL) | VAF 23/127 reads (18%) | called by mutect2, pindel, varscan2
- SIK2 | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SMURF2 | c.913A>C p.I305L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SMYD5 | c.619A>C p.K207Q | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST14 | c.201G>T p.L67F | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TAX1BP1 | c.2162A>G p.D721G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TRAV40 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- UGT2B10 | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- BLM | c.3045A>G p.T1015= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- CAPN13 | c.1347C>T p.Y449= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as rs1335454638; called by muse, mutect2
- CKS1B | c.198C>T p.I66= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV52699732; called by muse, mutect2
- COBL | c.2748C>T p.S916= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- DCBLD1 | c.1758C>G p.R586= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- GPR179 | c.3549G>A p.R1183= (on ENST00000621958; = p.R1182= on NM_001004334.4) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs1181090888; called by muse, mutect2, varscan2
- IER2 | c.273G>A p.P91= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1370100873; called by muse, varscan2
- PIEZO1 | c.2154C>T p.G718= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- RYR1 | c.5463C>T p.D1821= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as rs753150627, COSV62091944; called by muse, mutect2, varscan2
- SLC45A4 | c.1665C>T p.N555= (on ENST00000517878 / NM_001286646.2; = p.N504= on NM_001080431.2) | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs1049181128, COSV50140615; called by muse, mutect2, varscan2
- SLC46A1 | c.1201C>T p.L401= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV50229533; called by muse, mutect2, varscan2
- SPPL2B | c.288G>C p.G96= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs759610235; called by muse, mutect2, varscan2
- STK3 | c.1080C>T p.S360= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs764933237; called by muse, mutect2, varscan2
- WDR81 | c.2814T>C p.A938= | Silent (SNP) | VAF 32/126 reads (25%) | called by muse, mutect2, varscan2
- ZZEF1 | c.7377G>C p.L2459= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2
- ABCA8 | c.1789-322C>T | Intron (SNP) | VAF 87/218 reads (40%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1779C>T | RNA (SNP) | VAF 30/77 reads (39%) | catalogued as rs964057723; called by muse, mutect2, varscan2
- AFF4 | c.*302A>G | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- ATP5MG | c.*699C>T | 3'UTR (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- BACE1 | c.*2163A>C | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- BMP6 | c.*1194_*1200del | 3'UTR (DEL) | VAF 7/90 reads (8%) | called by mutect2, pindel*
- CBX8 | c.*1303del | 3'UTR (DEL) | VAF 10/52 reads (19%) | catalogued as rs879051781; called by mutect2, varscan2
- CDC42SE2 | c.*1964G>C | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- CDH6 | c.1882+342_1882+344del | Intron (DEL) | VAF 8/53 reads (15%) | catalogued as rs954140480; called by pindel, varscan2
- CDK10 | c.*419C>T | 3'UTR (SNP) | VAF 26/85 reads (31%) | catalogued as rs1297077568; called by muse, mutect2, varscan2
- CDK20 | c.843+28C>G | Intron (SNP) | VAF 55/346 reads (16%) | called by muse, mutect2, varscan2
- COX10 | c.696-14737C>T | Intron (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*2195A>C | 3'UTR (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- DDX19B | chr16:70294813 G>A | 5'Flank (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- DECR1 | c.*5A>C | 3'UTR (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- DSC2 | c.*130T>G | 3'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- DST | c.581+22T>C | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, varscan2
- DTX1 | c.-127G>C | 5'UTR (SNP) | VAF 38/66 reads (58%) | catalogued as COSV57496634; called by muse, mutect2, varscan2
- DUSP28 | c.394-91G>A | Intron (SNP) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- F13B | c.*156G>A | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- GCLC | chr6:53545039 T>C | 5'Flank (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- GIPC2 | c.*1683A>G | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- GOLGB1 | c.*143G>C | 3'UTR (SNP) | VAF 21/137 reads (15%) | catalogued as rs1050080492; called by muse, mutect2, varscan2
- IFT52 | c.*175T>C | 3'UTR (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- IGFL2 | c.20-150C>G | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as COSV66617348; called by muse, mutect2
- IL18R1 | c.*1612A>G | 3'UTR (SNP) | VAF 13/71 reads (18%) | catalogued as rs913749697; called by muse, mutect2, varscan2
- JAKMIP2 | c.-404C>A | 5'UTR (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- KAT6A | c.1483-2258T>C | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- KDSR | c.-25T>C | 5'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- KIAA1217 | c.*1143A>C | 3'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- KLHL30 | c.*431C>T | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+19500C>T | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- LYSMD2 | chr15:51737940 T>G | 5'Flank (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- MCF2L | c.369-567C>T | Intron (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- ME2 | c.*512C>G | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851192 G>A | 5'Flank (SNP) | VAF 40/128 reads (31%) | catalogued as rs755938787; called by muse, varscan2
- MIR5195 | chr14:106851236 A>G | 5'Flank (SNP) | VAF 40/144 reads (28%) | catalogued as rs529089085; called by muse, varscan2
- MRO | c.*1506A>G | 3'UTR (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- MYH16 | n.3535C>T | RNA (SNP) | VAF 10/31 reads (32%) | catalogued as rs988632686; called by muse, mutect2, varscan2
- OR2T2 | chr1:248441608 G>T | 5'Flank (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- OR4N1P | n.167C>T | RNA (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- PALD1 | c.*251T>G | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- PAX6 | c.10+1101G>A | Intron (SNP) | VAF 34/223 reads (15%) | catalogued as rs541893479; called by muse, mutect2, varscan2
- PPM1L | c.*8787A>G | 3'UTR (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- PPP3CA | c.*212A>C | 3'UTR (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- RBM7 | c.439-698G>A | Intron (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- RCC1 | c.73+595G>A | Intron (SNP) | VAF 20/59 reads (34%) | catalogued as rs777730618; called by muse, mutect2, varscan2
- RPUSD3 | c.724+24C>T | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as rs375440490; called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13284C>T | Intron (SNP) | VAF 18/70 reads (26%) | catalogued as rs1176577878, COSV56159498; called by muse, mutect2, varscan2
- SAMD3 | c.823-4994G>T | Intron (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- SLU7 | c.*820_*823del | 3'UTR (DEL) | VAF 5/34 reads (15%) | catalogued as rs1224571127; called by mutect2, pindel, varscan2
- THSD4 | c.*2132A>G | 3'UTR (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
- TMA16 | c.*812T>A | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- VWA1 | c.*2997G>A | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, varscan2
- ZFAND2A | chr7:1152234 G>A | 3'Flank (SNP) | VAF 9/109 reads (8%) | catalogued as rs1018922624; called by muse, mutect2
- ZNF680 | c.*5T>G | 3'UTR (SNP) | VAF 101/266 reads (38%) | called by muse, mutect2, varscan2
